Somatic mutation profile of tumor specimen ALCH-B2RV-TTP1-A (aliquot ALCH-B2RV-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.0 years (22,271 days).
Specimen ALCH-B2RV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffbfa212-462a-4ddb-8cac-f7903369cf18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RV-NB1-A (Blood Derived Normal), aliquot ALCH-B2RV-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8827f942-a16b-49f1-9cf8-5f4c7360525e

The open-access MAF lists 351 somatic variants for this specimen: 252 protein-altering or splice-affecting, 69 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 220, Silent 69, Nonsense Mutation 15, Intron 12, Splice Site 7, RNA 7, Frame Shift Del 5, 3'UTR 4, 5'UTR 3, 3'Flank 2, 5'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 23/208 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.926G>T p.R309L (on ENST00000392977 / NM_001286615.2; = p.R274L on NM_178826.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100152812, COSV100153324; called by muse, mutect2, varscan2
- AP1G2 | c.127del p.D43Tfs*30 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | catalogued as COSV58111047; called by mutect2, pindel
- ATP10B | c.3139C>A p.R1047S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs370681181; called by muse, mutect2, varscan2
- BIRC7 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV53902663; called by muse, mutect2, varscan2
- BRINP3 | c.1498C>A p.L500M | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100819409; called by muse, mutect2
- C1QA | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV65890096; called by muse, mutect2
- C1orf94 | c.1019C>G p.P340R (on ENST00000488417 / NM_001134734.2; = p.P150R on NM_032884.5) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100974593; called by muse, mutect2, varscan2
- CACNG3 | c.855C>A p.D285E | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV50079047; called by muse, mutect2
- CADPS | c.3497T>C p.I1166T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as rs774478977, COSV51895733; called by muse, mutect2, varscan2
- CASS4 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs1280406712, COSV64387198; called by muse, mutect2, varscan2
- CATSPER3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 57/420 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50948552; called by muse, mutect2, varscan2
- CCDC102B | c.119G>A p.C40Y | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs200430842; called by muse, mutect2
- CCDC40 | c.3245G>T p.R1082L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV56408550; called by muse, mutect2
- CEACAM20 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | catalogued as COSV100386923; called by muse, mutect2
- CENPW | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242445303; called by muse, mutect2, varscan2
- COL22A1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs761936657, COSV57342381; called by muse, mutect2, varscan2
- CRB1 | c.4174G>A p.E1392K | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV66347379; called by muse, mutect2
- CSHL1 | c.528G>C p.K176N (on ENST00000309894 / NM_022581.3; = p.K82N on NM_001318.4) | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as rs774503320; called by muse, mutect2
- CT47B1 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 75/663 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as rs775574378, COSV64890483; called by muse, mutect2, varscan2
- CUBN | c.5050G>T p.D1684Y | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64728344; called by muse, mutect2
- DAO | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756971224; called by muse, mutect2, varscan2
- DCSTAMP | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52580197; called by muse, mutect2
- DCTN2 | c.190A>G p.T64A (on ENST00000548249 / NM_001261413.2; = p.T69A on NM_006400.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV101461154; called by muse, mutect2
- DNAH11 | c.4629G>T p.W1543C | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322377546; called by muse, mutect2
- DNAJC27 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1212371401; called by muse, mutect2, varscan2
- DPP6 | c.1186G>T p.V396L (on ENST00000377770 / NM_001364500.2; = p.V334L on NM_001936.5) | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1451438931, COSV59629101, COSV59647742; called by muse, mutect2
- DTNA | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51991605; called by muse, mutect2, varscan2
- ERBIN | c.1825A>G p.M609V | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs760581110; called by muse, mutect2, varscan2
- F3 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs766879948; called by muse, mutect2, varscan2
- FAT3 | c.12124G>T p.G4042W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769677166; called by mutect2, varscan2
- FBN3 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560697; called by muse, mutect2, varscan2
- FBXW7 | c.1973G>C p.R658P (on ENST00000281708 / NM_001349798.2; = p.R578P on NM_018315.5) | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55905466; called by muse, mutect2
- FCRL5 | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs753816172; called by muse, mutect2
- FOXD4 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 32/1155 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58702174; called by muse, mutect2
- GABRG2 | c.805G>T p.V269L (on ENST00000361925 / NM_001375343.1; = p.V229L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as COSV62722476; called by muse, mutect2, varscan2
- GPC6 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65495587; called by muse, mutect2, varscan2
- GPR141 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.012); catalogued as rs1269855834; called by muse, varscan2
- GRIN2B | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199799650, COSV74204786, COSV74206480; called by muse, mutect2
- H3-5 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs1465746571; called by muse, mutect2
- HCN1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs771234977, COSV57507475, COSV57509060; called by muse, mutect2, varscan2
- HSPG2 | c.3888+8C>T | Splice Region (SNP) | VAF 28/398 reads (7%) | catalogued as rs903382701, COSV65971278; called by muse, mutect2
- HTR2C | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV52219021; called by muse, mutect2, varscan2
- IFI44L | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60729018; called by muse, mutect2
- KCNH2 | c.1103A>T p.H368L | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV51141725; called by muse, mutect2, varscan2
- KLRC1 | c.598del p.D200Tfs*14 | Frame Shift Del (DEL) | VAF 20/188 reads (11%) | catalogued as COSV61725548; called by mutect2, varscan2
- KMT2B | c.3946G>A p.V1316I | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1419395704, COSV99719526; called by muse, mutect2
- LRFN5 | c.1587G>T p.M529I | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99985037; called by muse, mutect2
- MASTL | c.1896C>A p.N632K | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs746395448; called by muse, mutect2
- MED12L | c.5470G>C p.G1824R | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56377412; called by muse, mutect2
- MPHOSPH6 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99259261; called by muse, mutect2
- MS4A2 | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 33/337 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs372506133; called by muse, mutect2, varscan2
- MYF5 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57354965; called by muse, mutect2
- MYH6 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs397516760, COSV62452601; ClinVar: uncertain significance; called by muse, mutect2
- MYO16 | c.3029G>C p.R1010P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100695006, COSV62762322; called by muse, mutect2, varscan2
- MYO7B | c.1135G>T p.G379W | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1437492957; called by muse, mutect2, varscan2
- NPY1R | c.473del p.G158Vfs*4 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | catalogued as COSV56715566; called by mutect2, pindel, varscan2
- NPY5R | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs552707275, COSV58451856; called by muse, mutect2
- OR10G8 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70908556, COSV70908802; called by muse, mutect2, varscan2
- OR4C15 | c.205C>A p.L69I (on ENST00000314644; = p.L15I on NM_001001920.2) | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.926); catalogued as COSV58951131; called by muse, mutect2, varscan2
- OR4C3 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs776698961; called by muse, mutect2, varscan2
- OR4C6 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | catalogued as COSV58603831, COSV58604646; called by muse, mutect2
- OR5D13 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs763757727, COSV62334485, COSV62334932; called by muse, mutect2
- OR8I2 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV56167102; called by muse, mutect2, varscan2
- PCDHA10 | c.294C>G p.S98R | Missense Mutation (SNP) | VAF 40/714 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.195); catalogued as rs1286159283; called by muse, mutect2
- PDE1C | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100372169; called by muse, mutect2
- PLCB4 | c.3459+1G>T p.X1153_splice | Splice Site (SNP) | VAF 9/100 reads (9%) | catalogued as rs1373299523; called by muse, mutect2
- POU4F2 | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55583296; called by muse, mutect2
- PPIL6 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1369169814; called by muse, mutect2
- PREX2 | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV55796249; called by muse, mutect2
- PRR32 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 38/450 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV64420566; called by muse, mutect2
- PSD3 | c.2428C>G p.R810G (on ENST00000440756; = p.R809G on NM_015310.4) | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676754; called by muse, mutect2, varscan2
- PTGIR | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs200866776; called by muse, mutect2, varscan2
- PTPRB | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs749761853; called by muse, mutect2
- PXDNL | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 38/496 reads (8%) | catalogued as COSV62476645; called by muse, mutect2
- RB1 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV57327592; called by muse, mutect2, varscan2
- RFPL4B | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV104437240; called by muse, mutect2
- RPEL1 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV71503356; called by muse, mutect2
- SORCS3 | c.2303C>A p.P768Q | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63796186; called by muse, mutect2
- SPATA31D1 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61196097; called by muse, mutect2
- TEKT4 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs782140897; called by muse, mutect2, varscan2
- TET2 | c.5669A>G p.N1890S | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs774179621, COSV54407276; called by muse, mutect2, varscan2
- TLN2 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs776572724; called by muse, mutect2
- TMEM145 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV56626481; called by muse, mutect2, varscan2
- UBC | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 51/602 reads (8%) | catalogued as rs751044489; called by muse, mutect2
- VPS36 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65199544; called by muse, mutect2, varscan2
- ZFAND4 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1281873896, COSV60861319; called by muse, mutect2
- ZFYVE21 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240406064; called by muse, mutect2
- ZNF205 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs1174867176; called by muse, mutect2, varscan2
- ZNF41 | c.1388G>C p.G463A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99058129; called by muse, mutect2
- ZNF804A | c.2050T>A p.Y684N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56439394; called by muse, mutect2, varscan2
- ABCC3 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- ACTRT1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2
- ADGRL3 | c.3257C>A p.T1086N (on ENST00000506720 / NM_001322402.2; = p.T1018N on NM_015236.6) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2
- AGRN | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHCTF1 | c.481-1G>T p.X161_splice (on ENST00000366508; = p.X135_splice on NM_015446.5) | Splice Site (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- AK5 | c.633T>A p.D211E (on ENST00000354567 / NM_174858.3; = p.D185E on NM_012093.4) | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2
- AMY2B | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 28/506 reads (6%) | called by muse, mutect2
- AMY2B | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 27/511 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ANAPC2 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANGPT4 | c.1448A>T p.Y483F | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ARHGAP40 | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL2 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT3 | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- BRD4 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); called by muse, mutect2
- BSN | c.3091G>T p.G1031W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BTK | c.837T>A p.Y279* | Nonsense Mutation (SNP) | VAF 8/205 reads (4%) | called by muse, mutect2
- C1GALT1 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2orf66 | c.260A>T p.Y87F | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C2orf66 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- C2orf66 | c.61G>T p.G21* | Nonsense Mutation (SNP) | VAF 15/169 reads (9%) | called by muse, mutect2
- C7orf57 | c.434G>T p.R145I | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CABLES2 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CACNA1G | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- CAPN2 | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC105 | c.1166C>A p.T389N | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, varscan2
- CCDC178 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CCDC8 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by mutect2, varscan2
- CD163 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CDADC1 | c.196C>G p.H66D | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CDH20 | c.415A>T p.R139W | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CEACAM20 | c.1223G>T p.W408L | Missense Mutation (SNP) | VAF 26/423 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CEACAM20 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- CENPJ | c.1464G>C p.Q488H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CIART | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.32); called by muse, mutect2
- CLDN11 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 87/674 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNBD1 | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CNTN3 | c.2954G>T p.S985I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CNTNAP4 | c.1940C>A p.T647N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CPM | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CPO | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.10275G>C p.M3425I (on ENST00000297405 / NM_001363185.1; = p.M3256I on NM_052900.3) | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.038); called by muse, mutect2
- CTNNA3 | c.2267G>T p.C756F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTSA | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.152); called by muse, mutect2
- CUBN | c.7118A>G p.H2373R | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- DCAF4L2 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 50/633 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2
- DDR2 | c.2284-1G>C p.X762_splice | Splice Site (SNP) | VAF 36/481 reads (7%) | called by muse, mutect2
- DLGAP4 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNMT1 | c.4660G>A p.A1554T | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DRGX | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- DSG4 | c.1840G>T p.G614W | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2
- ENPP3 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- EPHA6 | c.3142C>A p.P1048T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EXO1 | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLN2 | c.2900G>A p.C967Y | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCRL1 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 21/408 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); called by muse, mutect2
- FRMPD1 | c.4549C>A p.H1517N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.175); called by muse, mutect2
- FSCB | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.078); called by muse, mutect2
- GCNT2 | c.957G>T p.W319C (on ENST00000379597 / NM_001374747.1; = p.W317C on NM_001491.3) | Missense Mutation (SNP) | VAF 38/485 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- GDI1 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- GK5 | c.886G>T p.G296* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- GPBP1L1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- GPR182 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- GRIN3A | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 18/403 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2
- HCN1 | c.1625G>A p.C542Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HR | c.1594A>T p.T532S | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR1A | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HUWE1 | c.11584G>T p.E3862* | Nonsense Mutation (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- IDUA | c.1942C>G p.P648A | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 30/487 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- IGSF1 | c.3346A>T p.R1116W | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- INSL3 | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- INSYN2B | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- JAK2 | c.3063dup p.A1022Cfs*25 | Frame Shift Ins (INS) | VAF 38/114 reads (33%) | called by mutect2, pindel
- KDM6A | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- KIAA1210 | c.4072C>A p.Q1358K | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- KL | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.124); called by muse, mutect2
- KLHL33 | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2
- LAS1L | c.1346G>T p.R449M | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- LHX8 | c.388A>T p.R130* | Nonsense Mutation (SNP) | VAF 9/222 reads (4%) | called by muse, mutect2
- LMBR1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2
- LONRF1 | c.841-1G>A p.X281_splice | Splice Site (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- LRP2 | c.5936A>T p.Q1979L | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LTN1 | c.577-2A>T p.X193_splice | Splice Site (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- LYST | c.4159A>G p.T1387A | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- MAGEE1 | c.210del p.T71Pfs*42 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, varscan2
- MAP2 | c.4717G>T p.A1573S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MAPK8IP3 | c.515_516del p.I172Tfs*8 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | called by mutect2, pindel, varscan2
- MECOM | c.2061G>A p.M687I (on ENST00000468789 / NM_001105078.4; = p.M875I on NM_004991.4) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- METTL11B | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, varscan2
- MGAM | c.3739C>A p.Q1247K | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- MIA3 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.165); called by muse, mutect2
- MOGAT1 | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- MUC16 | c.37902G>C p.W12634C | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- MUC5B | c.13562G>A p.S4521N | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MYH15 | c.5489G>T p.R1830M | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- MYO5B | c.2334G>T p.W778C | Missense Mutation (SNP) | VAF 85/583 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NAV3 | c.4583C>T p.P1528L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEXMIF | c.2557G>T p.V853L | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2
- NKAP | c.1225A>T p.T409S | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2
- OR10V1 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2
- OR2A4 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 53/667 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2Z1 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR4C15 | c.781A>T p.I261F (on ENST00000314644; = p.I207F on NM_001001920.2) | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OR8K5 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTOG | c.5336dup p.E1780Rfs*13 | Frame Shift Ins (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- OTOG | c.6525C>A p.H2175Q | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.433); called by muse, mutect2
- PCDHGB6 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- PER2 | c.3278G>C p.S1093T | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PER2 | c.2017A>G p.S673G | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PFKP | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PHF14 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PITPNB | c.769-2A>C p.X257_splice | Splice Site (SNP) | VAF 40/179 reads (22%) | called by muse, mutect2, varscan2
- PKHD1 | c.7215+2T>A p.X2405_splice | Splice Site (SNP) | VAF 28/355 reads (8%) | called by muse, mutect2
- PLA1A | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- PLEKHG5 | c.1071G>T p.W357C (on ENST00000400915 / NM_001042663.3; = p.W320C on NM_020631.6) | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHO1 | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- PLIN3 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- POU3F3 | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.969); called by muse, varscan2
- PPP1R9B | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.43); called by muse, mutect2
- PTPRO | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- RET | c.985T>A p.F329I | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RFX4 | c.1369C>T p.H457Y (on ENST00000392842 / NM_213594.3; = p.H363Y on NM_032491.6) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- RPL7 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SASS6 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SETD1A | c.3019G>T p.E1007* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- SLC1A1 | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC6A19 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SPATA31D1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, mutect2
- SPATA31E1 | c.3025G>C p.G1009R | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.138); called by muse, mutect2
- SPTA1 | c.3123G>C p.M1041I | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- STYXL2 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- TAF1 | c.1063C>A p.P355T (on ENST00000373790 / NM_138923.4; = p.P376T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- TAP2 | c.1976T>A p.I659N | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TDRD15 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- TEX13A | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TGM6 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM132D | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TMEM71 | c.647G>C p.R216P (on ENST00000523829 / NM_001382398.1; = p.R197P on NM_144649.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS15 | c.2756T>C p.V919A | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.009); called by muse, mutect2
- TNFSF18 | c.598T>A p.*200Kext*45 | Nonstop Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- TPR | c.6971G>T p.R2324I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TPTE | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.012); called by muse, mutect2
- TRIM28 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM58 | c.654C>G p.S218R | Missense Mutation (SNP) | VAF 52/461 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRPM2 | c.3375G>T p.E1125D | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTC3 | c.2717G>T p.W906L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- TWIST1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- UBR5 | c.5414A>T p.Y1805F | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UGT3A2 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- UMOD | c.1214C>A p.T405N | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2
- UNC5A | c.1676A>T p.Y559F | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- USP45 | c.1118T>A p.V373E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- VNN3 | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.28); called by muse, mutect2
- WDR13 | c.1322C>A p.A441E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.313); called by muse, mutect2
- WDR64 | c.2339C>G p.A780G | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.039); called by muse, mutect2
- ZIC3 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.15); called by muse, mutect2
- ZNF43 | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2
- ZNF449 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- ZNF536 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF564 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF665 | c.1460G>T p.R487I (on ENST00000600412; = p.R552I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.121); called by muse, mutect2
- ACSL6 | c.795G>A p.P265= (on ENST00000379240; = p.P290= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/281 reads (10%) | catalogued as rs540864387, COSV57295411; called by muse, mutect2, varscan2
- ALG10B | c.729C>T p.S243= | Silent (SNP) | VAF 23/210 reads (11%) | called by muse, mutect2, varscan2
- AMPD3 | c.1992C>T p.D664= (on ENST00000396553 / NM_001025389.2; = p.D673= on NM_000480.3) | Silent (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2
- ASTN1 | c.3483C>T p.Y1161= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs1409184571; called by muse, mutect2, varscan2
- ATAD3C | c.42G>A p.Q14= | Silent (SNP) | VAF 29/314 reads (9%) | called by muse, mutect2
- BBS2 | c.288A>G p.T96= | Silent (SNP) | VAF 19/261 reads (7%) | called by muse, mutect2
- CDH2 | c.927G>T p.V309= | Silent (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- CDT1 | c.117C>T p.A39= | Silent (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- CMYA5 | c.3954A>G p.S1318= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs778376042; called by muse, mutect2, varscan2
- COL11A1 | c.4764A>G p.Q1588= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- CSMD2 | c.5955A>T p.P1985= | Silent (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- CUBN | c.5049G>A p.L1683= | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- DCAF12L2 | c.996G>T p.L332= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- DCSTAMP | c.507G>A p.Q169= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV99886789; called by muse, mutect2
- DIDO1 | c.1626A>G p.A542= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- DOCK6 | c.2982C>T p.N994= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs528600367; called by muse, mutect2
- EPPK1 | c.1491C>A p.T497= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- ERVV-2 | c.1200A>C p.A400= | Silent (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- FAM124B | c.118C>A p.R40= | Silent (SNP) | VAF 24/264 reads (9%) | catalogued as rs201610226; called by muse, mutect2
- FAM135B | c.3696G>T p.R1232= | Silent (SNP) | VAF 20/468 reads (4%) | called by muse, mutect2
- FAM153B | c.483T>C p.F161= (on ENST00000253490; = p.F84= on NM_001265615.1) | Silent (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- FAM50B | c.150G>A p.S50= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs1045601678, COSV100976630; called by muse, mutect2
- FOXD3 | c.570C>A p.R190= | Silent (SNP) | VAF 44/778 reads (6%) | called by muse, mutect2
- GAD2 | c.1578C>A p.L526= | Silent (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2, varscan2
- GDAP1 | c.162T>C p.H54= | Silent (SNP) | VAF 51/321 reads (16%) | catalogued as rs1236508750; called by muse, mutect2, varscan2
- GDI1 | c.465C>T p.P155= | Silent (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- GFRA4 | c.261G>T p.P87= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- HEATR4 | c.252C>A p.P84= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- HELZ2 | c.2877G>C p.R959= (on ENST00000467148 / NM_001037335.2; = p.R390= on NM_033405.3) | Silent (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- HEPH | c.2664C>A p.P888= (on ENST00000343002; = p.P621= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- HEY1 | c.726T>C p.P242= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs572139345; called by muse, mutect2, varscan2
- HMCN2 | c.2256G>T p.P752= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV70280606; called by muse, mutect2
- INSR | c.1185A>G p.L395= | Silent (SNP) | VAF 38/379 reads (10%) | catalogued as COSV57162850; called by muse, mutect2
- KCNK16 | c.564C>A p.P188= | Silent (SNP) | VAF 17/190 reads (9%) | called by muse, mutect2
- KLK5 | c.279C>T p.C93= | Silent (SNP) | VAF 26/280 reads (9%) | catalogued as rs201029495, COSV60450368; called by muse, mutect2
- KRTAP10-9 | c.132C>A p.T44= | Silent (SNP) | VAF 30/302 reads (10%) | called by muse, mutect2, varscan2
- MED26 | c.552G>C p.G184= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- MEST | c.93C>T p.I31= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV56229723; called by muse, mutect2, varscan2
- MRC1 | c.4233T>C p.Y1411= | Silent (SNP) | VAF 77/616 reads (13%) | called by muse, mutect2, varscan2
- MTUS1 | c.2688G>C p.A896= (on ENST00000262102 / NM_001363061.1; = p.A62= on NM_020749.4) | Silent (SNP) | VAF 31/271 reads (11%) | called by muse, mutect2, varscan2
- MUC17 | c.7431C>A p.S2477= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs777643517, COSV60289056; called by muse, mutect2, varscan2
- MYCBP2 | c.2247G>A p.R749= (on ENST00000357337; = p.R787= on NM_015057.5) | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as rs372000674; called by muse, mutect2, varscan2
- NLRP12 | c.1512C>T p.I504= | Silent (SNP) | VAF 64/660 reads (10%) | catalogued as COSV60755059; called by muse, mutect2
- NPAP1 | c.3339C>A p.G1113= | Silent (SNP) | VAF 15/388 reads (4%) | called by muse, mutect2
- NRXN3 | c.486C>A p.T162= | Silent (SNP) | VAF 13/276 reads (5%) | called by muse, mutect2
- OR13H1 | c.480C>T p.I160= | Silent (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- OR5K3 | c.291T>C p.C97= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs1559622811; called by muse, mutect2, varscan2
- OR7G3 | c.420C>A p.L140= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100555773; called by muse, mutect2, varscan2
- OXCT1 | c.1407T>C p.I469= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- PCDHB13 | c.51C>T p.S17= | Silent (SNP) | VAF 34/674 reads (5%) | called by muse, mutect2
- PCDHB3 | c.2265G>T p.L755= | Silent (SNP) | VAF 22/296 reads (7%) | catalogued as rs1554272709, COSV50636216; called by muse, mutect2, varscan2
- PCDHGB6 | c.588G>T p.L196= | Silent (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- PLEKHG3 | c.2667C>T p.A889= (on ENST00000394691; = p.A945= on NM_001308147.2) | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as rs1035809764; called by muse, mutect2
- PNPLA7 | c.2880G>A p.T960= | Silent (SNP) | VAF 19/221 reads (9%) | catalogued as rs757075506; called by muse, mutect2
- POTEF | c.2442C>A p.A814= | Silent (SNP) | VAF 74/633 reads (12%) | called by muse, mutect2, varscan2
- PRR9 | c.27G>A p.K9= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- PTGES2 | c.735G>T p.L245= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- PTPRH | c.3315G>T p.V1105= | Silent (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- RASSF7 | c.577C>T p.L193= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs1564824073; called by muse, mutect2, varscan2
- SPPL2C | c.771C>A p.G257= | Silent (SNP) | VAF 44/305 reads (14%) | called by muse, mutect2, varscan2
- SYN1 | c.90G>T p.P30= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- TBCD | c.1878A>T p.A626= | Silent (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- TNIK | c.1972C>A p.R658= | Silent (SNP) | VAF 58/492 reads (12%) | catalogued as COSV52673956; called by muse, mutect2, varscan2
- TRIML1 | c.537G>T p.V179= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- TRMT13 | c.1329G>A p.L443= | Silent (SNP) | VAF 16/277 reads (6%) | catalogued as rs1185794267; called by muse, mutect2
- UTRN | c.8139G>A p.V2713= | Silent (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- ZFHX4 | c.1536C>A p.S512= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- ZNF467 | c.489G>T p.G163= | Silent (SNP) | VAF 18/241 reads (7%) | called by muse, mutect2
- ZNF608 | c.384C>G p.P128= | Silent (SNP) | VAF 30/508 reads (6%) | called by muse, mutect2
- ABCC13 | n.3908G>T | RNA (SNP) | VAF 29/294 reads (10%) | called by muse, mutect2, varscan2
- AL133304.3 | n.327+32856A>T | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- AL590867.2 | n.62G>T | RNA (SNP) | VAF 58/448 reads (13%) | called by muse, mutect2, varscan2
- BOD1P2 | n.166G>T | RNA (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- CAPZB | c.*38A>G | 3'UTR (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- CFH | c.619+33C>A | Intron (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- CPLANE2 | chr1:16229515 G>A | 3'Flank (SNP) | VAF 12/209 reads (6%) | catalogued as rs1395238704; called by muse, mutect2
- DCUN1D4 | c.414+464G>T | Intron (SNP) | VAF 12/240 reads (5%) | catalogued as rs1327299798; called by muse, mutect2
- ERN2 | c.-24C>A | 5'UTR (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- FCAR | c.649+49C>A | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100628978; called by muse, mutect2, varscan2
- GABRE | c.784+1238G>C | Intron (SNP) | VAF 15/438 reads (3%) | called by muse, mutect2
- GUSBP10 | n.62T>C | RNA (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- KRT18P55 | n.696C>A | RNA (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- LACTB2 | c.286+947A>T | Intron (SNP) | VAF 32/404 reads (8%) | called by muse, mutect2
- MACROD2 | c.-41T>G | 5'UTR (SNP) | VAF 36/345 reads (10%) | called by muse, mutect2, varscan2
- MATK | c.*8C>A | 3'UTR (SNP) | VAF 15/144 reads (10%) | catalogued as rs568839886; called by muse, mutect2, varscan2
- NCKAP5L | c.3792+71T>A | Intron (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- NCOR1P1 | n.190C>A | RNA (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- NEB | c.8890-433T>C | Intron (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- PCDHGA2 | c.2424+42G>A | Intron (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- PLCB1 | c.594+1994G>C | Intron (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- PLEKHM1 | c.*1076C>T | 3'UTR (SNP) | VAF 37/308 reads (12%) | called by muse, mutect2, varscan2
- PYCR3 | chr8:143609578 C>T | 5'Flank (SNP) | VAF 8/80 reads (10%) | catalogued as rs1050024194; called by muse, mutect2
- RFX4 | c.44-7523A>T | Intron (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1406-58G>C | Intron (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- SLITRK2 | chrX:145827721 A>G | 3'Flank (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- SPR | chr2:72887406 C>A | 5'Flank (SNP) | VAF 15/84 reads (18%) | called by muse, varscan2
- TMPRSS13 | c.-31T>A | 5'UTR (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- TPI1 | c.*5C>T | 3'UTR (SNP) | VAF 76/513 reads (15%) | called by muse, mutect2, varscan2
- UBBP4 | n.1000C>G | RNA (SNP) | VAF 53/435 reads (12%) | called by muse, mutect2, varscan2
